Somatic mutation profile of tumor specimen TCGA-AA-3973-01A (aliquot TCGA-AA-3973-01A-01W-0995-10) from TCGA case TCGA-AA-3973, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.9 years (25,536 days).
Specimen TCGA-AA-3973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0746c3d-f787-4712-8498-57957945dd2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3973-10A (Blood Derived Normal), aliquot TCGA-AA-3973-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c66babe1-1005-4e4a-9f76-21f755d3fa4c

The open-access MAF lists 84 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 10, Frame Shift Ins 3, RNA 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAV3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs116840789, CM003421, COSV57481483; ClinVar: pathogenic; called by muse, mutect2
- DICER1 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58615689; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 103/129 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD17B | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100330020; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ANKFN1 | c.242T>A p.L81H | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100593059; called by muse, mutect2, varscan2
- ANKMY1 | c.1300dup p.D434Gfs*17 | Frame Shift Ins (INS) | VAF 18/31 reads (58%) | catalogued as rs760424033; called by mutect2, varscan2
- ARHGAP5 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs1308729348, COSV61534750; called by muse, mutect2, varscan2
- ATP7A | c.2473C>T p.L825F | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs1557234945, CD147027, COSV58455791; called by muse, mutect2, varscan2
- BZW1 | c.1081A>T p.K361* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV63350505; called by muse, mutect2, varscan2
- C12orf29 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV58357651; called by muse, mutect2, varscan2
- CCDC9 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs748559994, COSV55723068, COSV55723221; called by muse, mutect2, varscan2
- COL6A3 | c.6076G>A p.E2026K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770907851, COSV55109826; called by muse, mutect2, varscan2
- CREBBP | c.4870A>C p.T1624P | Missense Mutation (SNP) | VAF 235/667 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99268430; called by muse, mutect2, varscan2
- CSMD3 | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99823260; called by muse, mutect2, varscan2
- CYLD | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as rs770539079, COSV100282122; called by muse, mutect2, varscan2
- DICER1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 89/246 reads (36%) | catalogued as COSV58616785, COSV58629837; called by muse, mutect2, varscan2
- DIP2B | c.1631C>G p.S544W | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99997811; called by muse, mutect2, varscan2
- DMXL1 | c.6263G>T p.G2088V | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as rs1475895355, COSV60704157; called by muse, mutect2, varscan2
- EHD3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100434603, COSV100434868; called by muse, mutect2, varscan2
- EIF4A2 | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV56216956, COSV56217635, COSV99960966; called by muse, mutect2, varscan2
- EMC7 | c.696A>C p.K232N | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV99854690; called by muse, mutect2
- FERD3L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV51762036; called by muse, mutect2, varscan2
- FLT3LG | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as rs1413770713, COSV52621232; called by muse, mutect2, varscan2
- FMN2 | c.2559T>A p.C853* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100142340; called by muse, mutect2, varscan2
- FRMPD2 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV100563462; called by muse, mutect2, varscan2
- GDPGP1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1481246178, COSV61576365; called by muse, mutect2, varscan2
- GRIN2A | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV58031606, COSV58059418; called by muse, mutect2, varscan2
- GRIP1 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.4); catalogued as COSV99667831; called by muse, mutect2, varscan2
- HRG | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV51648961; called by muse, mutect2, varscan2
- KPNA5 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as COSV100706116, COSV62652428, COSV62655189; called by muse, mutect2, varscan2
- LRP2 | c.2885C>A p.S962* | Nonsense Mutation (SNP) | VAF 58/122 reads (48%) | catalogued as COSV55565738, COSV99786319; called by muse, mutect2, varscan2
- MAG | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs138056630; called by muse, mutect2, varscan2
- ME1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV100866308; called by muse, mutect2, varscan2
- NMD3 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768281274, COSV63618377; called by muse, mutect2, varscan2
- OPRD1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV52380139; called by muse, mutect2, varscan2
- OR9Q2 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 310/348 reads (89%) | SIFT tolerated (0.41); PolyPhen benign (0.257); catalogued as COSV100285291; called by mutect2, varscan2
- PCDHAC1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs782800214, COSV53838115; called by muse, mutect2, varscan2
- PIAS1 | c.1435A>G p.R479G | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV99986472; called by muse, mutect2
- PNRC1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.055); catalogued as rs370396619; called by muse, mutect2, varscan2
- PPP1R13B | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 77/206 reads (37%) | catalogued as rs759732294, COSV52454093; called by muse, mutect2, varscan2
- PREP | c.1787G>A p.R596H (on ENST00000369110; = p.R662H on NM_002726.5) | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs774977355, COSV64872632; called by muse, mutect2, varscan2
- RAET1E | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61723377; called by muse, mutect2
- RBM12B | c.1706C>G p.P569R | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs150172581, COSV101234463; called by muse, varscan2
- RILP | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV53961881; called by muse, mutect2, varscan2
- RXFP2 | c.2036dup p.L680Pfs*4 | Frame Shift Ins (INS) | VAF 244/379 reads (64%) | catalogued as rs753136741; called by mutect2, varscan2
- SAFB | c.2696G>T p.G899V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52654624; called by muse, mutect2, varscan2
- SARDH | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 90/122 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs563709194, COSV64099787; called by muse, varscan2
- SLC39A12 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV101069819; called by muse, mutect2
- SMAD4 | c.106_135del p.A36_K45del | In Frame Del (DEL) | VAF 29/44 reads (66%) | catalogued as COSV61696008; called by mutect2, pindel, varscan2
- SPDYE1 | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.129); catalogued as COSV99323839, COSV99324018; called by muse, mutect2
- SPRR3 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs374824766; called by muse, varscan2
- SRRM4 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.073); catalogued as rs750601249, COSV57412746, COSV99939730; called by muse, mutect2, varscan2
- SSX3 | c.330+1G>T p.X110_splice | Splice Site (SNP) | VAF 76/277 reads (27%) | catalogued as COSV100034972; called by muse, mutect2, varscan2
- TMBIM4 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs746695806, COSV99660167; called by muse, mutect2, varscan2
- TNFRSF11B | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV99816362; called by muse, mutect2, varscan2
- TNIK | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 287/708 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV99454761; called by muse, mutect2, varscan2
- TRMO | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs753673780, COSV64293702; called by muse, mutect2, varscan2
- TTC3 | c.2116A>G p.K706E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100694959; called by muse, mutect2
- USP43 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 32/868 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99556301; called by muse, mutect2
- ZNF335 | c.2022G>A p.G674= | Splice Region (SNP) | VAF 24/57 reads (42%) | catalogued as rs543763444, COSV59820867; called by muse, mutect2, varscan2
- GNB4 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 183/541 reads (34%) | called by mutect2, pindel, varscan2
- OR10H2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- PRPF40A | c.2700_2703del p.R901Vfs*73 | Frame Shift Del (DEL) | VAF 48/480 reads (10%) | called by mutect2, pindel
- BCAN | c.1239C>T p.D413= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs147038529, COSV61258675; called by muse, mutect2, varscan2
- CAMP | c.315C>T p.D105= (on ENST00000296435; = p.D102= on NM_004345.5) | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs201842351, COSV56482414; called by muse, mutect2, varscan2
- CLUH | c.3456C>T p.V1152= (on ENST00000435359; = p.V1191= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs778697020, COSV70930217; called by muse, varscan2
- CTTNBP2NL | c.63G>A p.E21= | Silent (SNP) | VAF 67/82 reads (82%) | catalogued as COSV54747726; called by muse, mutect2, varscan2
- DACT1 | c.1815G>A p.T605= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs966956659, COSV60022877; called by muse, mutect2
- DHX37 | c.1632G>A p.P544= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as rs900899087, COSV100438932; called by muse, mutect2, varscan2
- FFAR1 | c.528G>A p.P176= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs777875100, COSV50074714; called by muse, mutect2, varscan2
- FGF12 | c.132C>T p.H44= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs752899505, COSV53192939; called by muse, mutect2, varscan2
- GLIPR1L2 | c.135G>A p.L45= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as COSV57556804; called by muse, mutect2, varscan2
- NPHP1 | c.762G>A p.A254= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs755736458, COSV57211759; called by muse, mutect2, varscan2
- PTGIS | c.1113C>T p.D371= | Silent (SNP) | VAF 144/390 reads (37%) | catalogued as rs561620152, COSV54836179; called by muse, mutect2
- PXDN | c.2433C>T p.D811= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs776692929, COSV53248252; called by muse, mutect2, varscan2
- REV1 | c.3174G>A p.K1058= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1325438448, COSV51491436, COSV99177224; called by muse, mutect2, varscan2
- SLC25A20 | c.489T>C p.F163= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV59805085; called by muse, mutect2, varscan2
- SNPH | c.435C>T p.L145= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV60588173, COSV60591446; called by muse, mutect2
- TRANK1 | c.4371G>A p.K1457= | Silent (SNP) | VAF 108/244 reads (44%) | catalogued as COSV57166877; called by muse, mutect2, varscan2
- XPR1 | c.60C>A p.I20= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV62561264; called by muse, mutect2, varscan2
- ARPP19P2 | n.127C>T | RNA (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
